Somatic mutation profile of tumor specimen ALCH-AF43-TTP1-A (aliquot ALCH-AF43-TTP1-A-4-0-D-A627-36) from ALCHEMIST case ALCH-AF43, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.6 years (26,892 days).
Specimen ALCH-AF43-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9078e1ef-ea84-46f7-b1ec-cc14b1eeb8c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AF43-NB1-A (Blood Derived Normal), aliquot ALCH-AF43-NB1-A-1-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b62a8af-f4b7-478d-97c6-6f0c704caf27

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 2, Intron 2, Splice Region 1, RNA 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 49/458 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.646G>T p.V216L | Missense Mutation (SNP) | VAF 18/290 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs730882025, CM159291, CX952222, COSV52671096, COSV52751864, COSV53384298; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- BHMT2 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as rs369672073; called by muse, mutect2
- DDX54 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1232061328; called by muse, mutect2
- FLG | c.12091T>A p.Y4031N | Missense Mutation (SNP) | VAF 34/498 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.127); catalogued as rs1179866935; called by muse, mutect2
- GPR173 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1556805906; called by muse, mutect2
- KEL | c.1204-3T>C | Splice Region (SNP) | VAF 8/152 reads (5%) | catalogued as rs748896471; called by muse, mutect2
- SLC7A9 | c.376G>T p.A126S | Missense Mutation (SNP) | VAF 12/215 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.516); catalogued as CM010445; called by muse, mutect2
- SPTA1 | c.4068C>G p.I1356M | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.818); catalogued as COSV100934109, COSV100934758, COSV63749559; called by muse, mutect2
- SSBP4 | c.469del p.R157Gfs*44 | Frame Shift Del (DEL) | VAF 3/17 reads (18%) | catalogued as rs1568354539, COSV99526110; called by pindel, varscan2
- AKR1C8P | c.407C>G p.A136G | Missense Mutation (SNP) | VAF 19/336 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.03); called by muse, mutect2
- C2orf74 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.019); called by muse, mutect2
- CNOT1 | c.6158C>T p.A2053V | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.268); called by muse, mutect2
- SPTAN1 | c.2170G>T p.E724* | Nonsense Mutation (SNP) | VAF 9/234 reads (4%) | called by muse, mutect2
- SRPX2 | c.1015T>C p.Y339H | Missense Mutation (SNP) | VAF 24/540 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.025); called by muse, mutect2
- SUPT6H | c.3434A>T p.N1145I | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); called by muse, mutect2
- HSP90B1 | c.222A>G p.E74= | Silent (SNP) | VAF 9/284 reads (3%) | called by muse, mutect2
- MYLK2 | c.831G>T p.G277= | Silent (SNP) | VAF 14/103 reads (14%) | called by muse, mutect2, varscan2
- AC068587.7 | n.153C>T | RNA (SNP) | VAF 5/72 reads (7%) | catalogued as rs1216539076; called by muse, mutect2
- CD99L2 | c.130+1847G>A | Intron (SNP) | VAF 12/201 reads (6%) | catalogued as rs1557421002; called by muse, mutect2
- DDX5 | c.44+304C>T | Intron (SNP) | VAF 22/241 reads (9%) | called by muse, mutect2
